BEATAML1.0 case 2677 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/fcd24b34-4723-42d4-95a5-7b62a2e40bb6

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, minimal differentiation: ICD-O-3 morphology code: 9872/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,422 days); Progression or recurrence: no.

Biospecimens (3 samples)
- Sample BA3184D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA3289D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA3289R: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
